Gene-level copy-number profile of tumor specimen TCGA-B5-A5OC-01A from TCGA case TCGA-B5-A5OC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.5 years (26,109 days).
Specimen TCGA-B5-A5OC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.22249761-29c5-4139-b7fc-5885ccae52f5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A5OC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a821d9cf-960f-4934-b778-226204ba7999

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 1: 90; copy number 2: 53,559; copy number 3: 3,482; copy number 4: 2,594; copy number 5: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A5OC-01A-21D-A27O-01): tumor purity 0.47, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:22,722,229–22,722,469, 1 gene, copy number 5: RPS27P22.
- chr15:25,056,860–25,081,378, 13 genes, copy number 5: SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.
- chr19:15,673,018–15,697,174, 1 gene, copy number 5 (within-gene range 2–5): CYP4F12.

Autosomal genes at a single copy (total copy number 1): 89. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
